FM case AD7055 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/28ebcd3b-6545-4ded-bf62-81ed63ecbdda

Male, 75.6 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
